Somatic mutation profile of tumor specimen MBCProject_3554_T2_WES (aliquot MBCProject_3554_T2_WES_1) from CMI case MBCProject_3554, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.7 years (13,773 days).
Specimen MBCProject_3554_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a7b6874-257c-4b50-8518-323acf83d3d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3554_SALIVA (Saliva), aliquot MBCProject_3554_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c239360-4b54-42bd-bfed-41bec40a4f86

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Intron 3, Nonsense Mutation 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 20/323 reads (6%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2
- ACSL6 | c.913G>T p.E305* (on ENST00000379240; = p.E330* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | catalogued as COSV57306869; called by muse, mutect2, varscan2
- ACTB | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs1484491064, COSV59318696, COSV59320746; called by muse, mutect2
- AKAP17A | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58309975; called by muse, mutect2
- AKAP3 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV57421368; called by muse, mutect2
- ARFGEF1 | c.5467C>T p.L1823F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879166392; called by muse, mutect2
- ASCC3 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100226515; called by muse, mutect2
- CHD6 | c.7528G>C p.E2510Q | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100951193; called by muse, mutect2
- CXorf66 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV65168879; called by muse, mutect2
- KIF16B | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs1196534746, COSV61702649; called by muse, mutect2
- LMOD2 | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1409213172; called by muse, mutect2
- NTRK2 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV52885120; called by muse, mutect2
- NYNRIN | c.5578C>G p.L1860V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.071); catalogued as rs1174108616; called by muse, mutect2
- OLR1 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV58872315; called by muse, mutect2
- PCDHA10 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 40/724 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs962164938, COSV100254217; called by muse, mutect2
- PRLHR | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53305019; called by muse, mutect2
- SCN5A | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs759584454, COSV61135533, COSV99048706; ClinVar: uncertain significance; called by mutect2, varscan2
- SGCG | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV54566249; called by muse, mutect2
- TAF2 | c.2779C>G p.L927V | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65419241, COSV65419724; called by muse, mutect2
- CKAP2L | c.1537G>C p.A513P | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.92); called by muse, mutect2
- CYP4A22 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2
- GAS1 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GRIK2 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2
- H2BC17 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- LEFTY2 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH7 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2
- PLXNB2 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2
- PTEN | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- RANBP2 | c.4430C>T p.S1477F | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2
- RFX5 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); called by muse, mutect2
- RIMS2 | c.4366G>C p.E1456Q (on ENST00000666250 / NM_001348490.2; = p.E1027Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/262 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RSL24D1 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- SCARF1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- SCN7A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC25A45 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- SMURF1 | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TIAM1 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- TMEM161B | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2
- USH2A | c.12934G>C p.D4312H | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- XXYLT1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, varscan2
- ZNF488 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2
- CARNMT1 | c.705C>G p.L235= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- EP400 | c.8892C>T p.I2964= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- GALNT12 | c.639G>T p.L213= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- GIGYF1 | c.2883G>C p.R961= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- HS6ST3 | c.1089C>G p.L363= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as COSV65003911; called by muse, mutect2
- OTX2 | c.864T>G p.V288= (on ENST00000408990 / NM_172337.3; = p.V296= on NM_021728.4) | Silent (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- RYK | c.1521G>A p.R507= (on ENST00000620660 / NM_001005861.2; = p.R504= on NM_002958.4) | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- TXNDC16 | c.118T>C p.L40= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- CD8A | c.*351G>A | 3'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- EFHC1 | c.723+615C>T | Intron (SNP) | VAF 20/272 reads (7%) | catalogued as rs1381438361; called by muse, mutect2
- MARF1 | chr16:15643372 G>A | 5'Flank (SNP) | VAF 16/408 reads (4%) | catalogued as rs913853637; called by muse, mutect2
- SRL | c.62-2841G>A | Intron (SNP) | VAF 10/189 reads (5%) | catalogued as rs1458239526; called by muse, mutect2
- TRO | c.1700+21C>T | Intron (SNP) | VAF 8/124 reads (6%) | catalogued as rs963271023, COSV51508343; called by muse, mutect2
